TCGA case TCGA-05-4245 — Lung Adenocarcinoma (TCGA-LUAD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Bronchus and lung; Tissue source site: Indivumed. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/03d09c05-49ab-4ba6-a8d7-e7ccf71fafd2

Demographics
Sex at birth: male; Country of residence at enrollment: Germany; Age at index: 81 years; Vital status: Alive.

Diagnoses (3)
1. Adenocarcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8140/3; ICD-10 code: C34.1; Tissue or organ of origin: Upper lobe, lung; Site of resection or biopsy: Lung, NOS; Laterality: Left; Classification of tumor: primary; Age at diagnosis: 81.2 years (29,647 days); Year of diagnosis: 2009; AJCC staging edition: 6th; AJCC pathologic T: T2; AJCC pathologic N: N2; AJCC pathologic M: M0; AJCC pathologic stage: Stage IIIA; Prior malignancy: yes; Synchronous malignancy: No; Prior treatment: No; Residual disease: R2.
   Recorded as not given: adjuvant Pharmaceutical Therapy, NOS; adjuvant Radiation Therapy, NOS.
2. Prior malignancy of the descending colon (histology not recorded by GDC). AJCC pathologic T: T3; AJCC pathologic N: N1; AJCC pathologic M: M0.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Treatment anatomic sites: Body, total.
   Recorded as not given: Radiation Therapy, NOS.
3. Diagnosis record without a diagnosis name: Tumor of origin: diagnosis 1 of this record; Age at diagnosis: 82.1 years (29,981 days); Days to diagnosis: 334 days; Prior treatment: Yes.
   Recorded as not given: Pharmaceutical Therapy, NOS; Radiation Therapy, NOS.

Follow-up (3 entries)
- Day 334 (post initial treatment): Progression or recurrence: Yes.
- Days to follow up: 395 days (1.1 years); Disease response: Tumor Free.
- Days to follow up: 730 days (2.0 years); Disease response: Tumor Free.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Current Reformed Smoker for < or = 15 yrs; Pack years smoked: 32.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-05-4245-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Longest dimension: 0.9; Intermediate dimension: 0.7; Shortest dimension: 0.5.
  Slide TCGA-05-4245-01A-01-BS1: Section location: Bottom; Percent tumor cells: 50; Percent tumor nuclei: 65; Percent normal cells: 10; Percent necrosis: 15; Percent stromal cells: 25; Percent lymphocyte infiltration: 2.
  Slide TCGA-05-4245-01A-01-TS1: Section location: Top; Percent tumor cells: 65; Percent tumor nuclei: 75; Percent necrosis: 15; Percent stromal cells: 20; Percent lymphocyte infiltration: 2.
- Sample TCGA-05-4245-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-05-4245-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Submitted tumor site: Lung; Histologic diagnosis: Lung Adenocarcinoma- Not Otherwise Specified (NOS); History neoadjuvant treatment: No; Prospective collection: No; Retrospective collection: Yes; Tumor status: Tumor free; Tobacco smoking history indicator: 4; Anatomic organ subdivision: L-Upper.
- Follow-up form: Lost to follow-up: No; New tumor event diagnosis indicator: Yes; Tumor status: Tumor free; New tumor event radiation treatment: No; New tumor event pharmaceutical treatment: No; Treatment outcome at TCGA followup: Complete Remission/Response.
- Other malignancy form: Malignancy type: Prior Malignancy; Other malignancy histological type: Malignant neoplasm of colon.
- Other malignancy form, Surgery: Days from index date to other malignancy surgery: -1066.
- Other malignancy form, Drug treatment: Pharmaceutical therapy extent: Systemic.

GDC annotations on this case (curator notes; quoted as recorded):
- History of unacceptable prior treatment related to a prior/other malignancy: Prior malignancy colon cancer treated with systemic chemotherapy.
- Prior malignancy: Prior malignancy colon cancer treated with systemic chemotherapy.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 730 days; disease-specific survival: no event (censored), 730 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 334 days.
